Gene-level copy-number profile of tumor specimen ALCH-B2Y7-TTP1-A from ALCHEMIST case ALCH-B2Y7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 39.0 years (14,235 days).
Specimen ALCH-B2Y7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f133cdb9-534c-4e46-9917-29b91cb0e75a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2Y7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/f772ce49-d3f1-4433-8e3b-5430afe91b4e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 801; copy number 2: 56,991; copy number 3: 492; copy number 4: 40; copy number 5: 6; copy number 6: 6; copy number 7: 1; copy number 8: 1; copy number 15: 1; copy number 47: 3.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:225,886,282–225,924,278, 2 genes (within-gene range 0–1): LEFTY1, AL117348.2.
- chr2:91,578,478–91,580,863, 2 genes: AC233266.1, AC233266.2.
- chr2:231,592,864–231,594,276, 1 gene: TEX44.
- chr4:39,710,085–39,714,451, 2 genes (within-gene range 0–1): Y_RNA, AC108471.1.
- chr5:69,068,925–69,069,200, 1 gene: SUMO2P4.
- chr5:181,306,502–181,342,213, 3 genes: AC138035.1, AC138035.3, AC138035.2.
- chr7:76,389,334–76,409,697, 1 gene (within-gene range 0–1): SSC4D.
- chr7:140,435,316–140,435,787, 1 gene: AC069335.1.
- chr8:144,789,765–144,811,169, 3 genes: RPL8, MIR6850, ZNF517.
- chr9:131,096,476–131,123,152, 1 gene: AIF1L.
- chr15:22,867,052–22,981,063, 1 gene (within-gene range 0–1): CYFIP1.
- chr16:89,818,179–89,871,319, 1 gene: SPIRE2.
- chr16:89,919,165–89,938,761, 3 genes (within-gene range 0–1): AC092143.1, AC092143.2, TUBB3.
- chr16:89,969,773–89,972,832, 1 gene (within-gene range 0–1): CENPBD1.
- chr16:90,039,761–90,047,773, 1 gene (within-gene range 0–1): URAHP.
- chr17:2,755,705–3,037,741, 2 genes (within-gene range 0–1): RAP1GAP2, AC015921.1.
- chr19:453,134–453,245, 1 gene (within-gene range 0–2): RNA5SP462.
- chr19:9,019,344–9,115,763, 5 genes: BOLA3P2, OR1M4P, OR1M1, OR7G2, OR7G1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:946,315–981,300, 2 genes, copy number 5: AC122719.1, AC122719.2.
- chr9:136,738,167–136,758,543, 2 genes, copy number 6 (within-gene range 6–9): LCN10, LCN8.
- chr9:136,791,344–136,800,595, 2 genes, copy number 6 (within-gene range 1–6): TMEM141, AL355987.3.
- chr9:136,844,415–136,860,799, 3 genes, copy number 47 (within-gene range 3–47): AJM1, PHPT1, MAMDC4.
- chr14:104,681,146–104,722,535, 2 genes, copy number 5 (within-gene range 2–5): INF2, AL583722.3.
- chr14:105,583,731–105,601,728, 2 genes, copy number 6–7 (within-gene range 0–7): IGHA2, IGHE.
- chr15:22,401,208–22,406,944, 1 gene, copy number 15: SPATA31E3P.
- chr16:991,151–1,000,926, 1 gene, copy number 8: AC009041.1.
- chr16:1,088,226–1,105,461, 2 genes, copy number 5: C1QTNF8, AL031713.1.

Autosomal genes at a single copy (total copy number 1): 777. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
